Gene-level copy-number profile of tumor specimen TCGA-FW-A5DX-01A from TCGA case TCGA-FW-A5DX, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 71.4 years (26,067 days).
Specimen TCGA-FW-A5DX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.c7d6f146-a5fc-4115-b0a5-52c51e0fa17d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FW-A5DX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1169eb96-5a5d-400e-9ccf-6c7ac51b7fd3

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 2,214; copy number 3: 13,210; copy number 4: 12,204; copy number 5: 13,757; copy number 6: 8,789; copy number 7: 657; copy number 8: 3,272; copy number 9: 1,508; copy number 10: 3,660; copy number 11: 147; copy number 13: 45; copy number 14: 7; copy number 15: 298; copy number 16: 1; copy number 19: 8; copy number 20: 22; copy number 21: 6; copy number 22: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FW-A5DX-01A-11D-A27J-01): tumor purity 0.86, ploidy 5.07, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 9,607 genes in 34 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:20,248,691–20,452,947, 5 genes, copy number 8 (within-gene range 5–8): PUM2, SLC7A15P, RNA5SP86, RHOB, AC023137.1.
- chr2:21,932,662–22,536,322, 1 gene, copy number 21 (within-gene range 5–21): AC096570.1.
- chr2:22,317,053–23,927,123, 15 genes, copy number 20–22 (within-gene range 6–22): AC099799.1, RNA5SP87, LINC01830, LINC01884, RN7SKP27, AC018467.1, AC012506.1, AC012506.3, AC012506.2, AC012506.4, KLHL29, AC011239.1, AC011239.2, AC009242.1, ATAD2B.
- chr2:24,789,734–24,972,094, 7 genes, copy number 19: PTRHD1, CENPO, ADCY3, AC012073.1, DNAJC27, RPS13P5, SNORD14.
- chr2:25,697,076–25,697,188, 1 gene, copy number 19: Y_RNA.
- chr2:27,130,756–27,307,439, 10 genes, copy number 20 (within-gene range 5–20): PREB, PRR30, TCF23, AC013403.1, SLC5A6, ATRAID, CAD, SLC30A3, DNAJC5G, TRIM54.
- chr2:56,750,300–57,430,693, 4 genes, copy number 21–22 (within-gene range 7–22): PPIAP63, EIF2S2P7, AC132153.1, AC068276.1.
- chr2:57,907,629–59,063,766, 8 genes, copy number 20 (within-gene range 5–20): VRK2, AC068193.1, FANCL, AC007250.1, EIF3FP3, LINC01795, LINC01122, AC007238.1.
- chr2:59,218,680–60,100,200, 1 gene, copy number 8 (within-gene range 5–16): AC007100.1.
- chr2:59,434,552–59,442,261, 1 gene, copy number 16: AC007179.1.
- chr2:59,694,762–61,710,978, 44 genes, copy number 8: RNA5SP94, AC007100.2, AC007132.1, MIR4432HG, AC007381.1, RNU1-32P, MIR4432, BCL11A, AC009970.1, RN7SL361P, IFITM3P9, RPL26P13, RNU6-612P, ATP1B3P1, PAPOLG, LINC01185, RN7SL632P, RPL21P33, REL, RNU4-51P, AC010733.1, NONOP2, RPS12P3, PUS10, RNA5SP95, PEX13, KIAA1841, AC016747.4, AC016747.1, C2orf74, AC016747.2, AHSA2P, USP34, AC016747.3, AC018889.1, AC016894.1, SNORA70B, AC016727.1, XPO1, AC016727.3, AC016727.2, RPS29P10, RNU6-1145P, AC108039.1.
- chr4:55,938,153–56,033,361, 2 genes, copy number 7: AC110611.2, CEP135.
- chr4:56,097,390–56,097,504, 1 gene, copy number 7: RNA5SP161.
- chr4:107,203,349–108,035,174, 10 genes, copy number 7 (within-gene range 4–7): RAC1P5, AC104663.1, RNU6-551P, PAPSS1, SGMS2, CYP2U1-AS1, RNU6-733P, CYP2U1, AC096564.1, HADH.
- chr4:110,278,185–110,642,123, 9 genes, copy number 7: RNU6-205P, ZBED1P1, ENPEP, RPL7L1P13, ZNF969P, AC093872.1, AC098798.1, PANCR, PITX2.
- chr4:112,637,107–114,104,225, 30 genes, copy number 7: LARP7, MIR302CHG, MIR367, MIR302D, MIR302A, MIR302C, MIR302B, OSTCP4, AC106864.1, WRBP1, AC017007.3, Y_RNA, RPL7AP30, AC017007.4, ANK2, AC017007.2, AC017007.5, AC017007.1, ANK2-AS1, AC093879.1, MIR1243, MIR8082, AC004057.1, RN7SL184P, RNU1-138P, CAMK2D, AC111193.1, ARSJ, AC104779.1, AC093815.1.
- chr5:58,198–1,309,377, 48 genes, copy number 15: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, AC026740.2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457.
- chr5:31,400,497–45,895,970, 250 genes, copy number 15 (within-gene range 3–15) (broad region; genes not listed).
- chr6:2,245,718–2,525,976, 1 gene, copy number 8 (within-gene range 4–8): GMDS-DT.
- chr6:2,353,427–4,087,344, 54 genes, copy number 8: AL031768.2, AL031768.1, AL359852.2, AL359852.1, LINC02521, LINC01600, MYLK4, WRNIP1, SERPINB1, SERPINB9P1, MIR4645, SERPINB9, AL133351.2, AL133351.1, SERPINB6, LINC01011, NQO2, NQO2-AS1, HTATSF1P2, AL133351.4, AL133351.3, FAM136BP, SERPINB8P1, AL031963.2, RIPK1, AL031963.3, RNA5SP201, BPHL, AL031963.1, TUBB2A, TUBB2BP1, LINC02525, TUBB2B, PSMG4, SLC22A23, AL445309.1, AL033523.1, AL033523.2, PXDC1, AL391422.4, AL391422.1, AL391422.3, AL391422.2, FAM50B, AL590004.3, AL590004.2, AL590004.1, TDGF1P4, GLRX3P2, AL138831.3, AL138831.2, AL138831.1, PRPF4B, FAM217A.
- chr6:64,631,205–64,631,682, 1 gene, copy number 7: HNRNPDP2.
- chr7:70,972–159,233,377, 3,014 genes, copy number 10 (broad region; genes not listed).
- chr8:150,584–43,674,591, 947 genes, copy number 7–8 (broad region; genes not listed).
- chr8:79,520,145–113,950,998, 539 genes, copy number 7–9 (broad region; genes not listed).
- chr8:124,044,395–145,066,685, 394 genes, copy number 8–14 (within-gene range 6–14) (broad region; genes not listed).
- chr9:5,629,025–6,331,900, 14 genes, copy number 7–8 (within-gene range 4–8): RIC1, AL136980.1, ERMP1, AK4P4, KIAA2026, MLANA, MIR4665, RANBP6, AL162384.1, GTF3AP1, IL33, AL360221.1, SELENOTP1, TPD52L3.
- chr9:6,415,145–6,449,558, 1 gene, copy number 7: AL133480.1.
- chr12:12,116,025–25,409,445, 214 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr12:25,423,600–25,441,052, 3 genes, copy number 8: AC092451.2, FAM133GP, TUBB4BP1.
- chr13:27,343,687–49,585,558, 389 genes, copy number 7 (broad region; genes not listed).
- chr16:3,222,325–9,156,881, 147 genes, copy number 11 (within-gene range 6–11) (broad region; genes not listed).
- chr18:47,390–80,247,514, 1,239 genes, copy number 8 (broad region; genes not listed).
- chr20:87,250–64,313,132, 1,458 genes, copy number 9–10 (broad region; genes not listed).
- chr21:10,328,411–46,665,124, 745 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
